Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A6C8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A6C8-06A (Metastatic).

[page 1 of 2]
ICD-0-3
Melanoma, malignant NOS
8720/3
Site Axillary lymph node
C77.3
JW 5/24/13

NEW DOCUMENT:

Specimen Received:

- A: Skin, excision, left upper abdomen
- B: Skin, excision, left shoulder
- C: Axillary node dissection

Final Pathologic Diagnosis:

- A. Skin, excision, left upper abdomen:
Compound nevus, margins free
Lentigo (incidental finding)
- B. Skin, excision, left shoulder:
No residual malignant melanoma
Reparative changes consistent with previous operative site
Intradermal nevus (incidental finding)
- C. Axillary node dissection:
2 of 14 lymph nodes involved by metastatic melanoma
Extracapsular extension present
Largest dimension of tumor 2 cm
Findings supported by positive melan A, S-100

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received are three containers labeled with the patient's name.

Part A is additionally labeled "left upper abdomen" and consists of an excision of skin, 2.2 x 1.7 x 0.9 cm. A clip designates the 12 o'clock margin. The 9 - 3 o'clock margin is inked black; the 3 - 9 o'clock margin is inked blue. The specimen is submitted as follows: 9 o'clock tip in A1, 3 o'clock tip in A2 and mid portion in A3 & A4 (sequentially sectioned).

Part B is additionally labeled "left shoulder" and consists of an excision of skin, 8.7 x 3.7 x 0.8 cm. A clip designates the 3 o'clock margin. The 12 - 6 o'clock margin is inked blue; the 6 - 12 o'clock margin is inked black. The specimen is submitted as follows: 12 o'clock tip in B1, 6 o'clock tip in B2 and mid portion in B3 B17 (submitted sequentially from 12 to 6 o'clock).

Part C is additionally labeled "axillary node dissection" and consists of an aggregate of yellow/tan fibroadipose tissue, 11.0 x 10.0 x up to 4.0 cm. Sectioning reveals a few lymph nodes that range from 0.3 cm up to 5.5 cm. The largest mass is a tan/white to gray/brown, cut surface. Multiple whole lymph nodes in C1, one whole lymph node in C2, one lymph node bisected in C3, representative portions from mid size suspicious lymph node in C4,

Criteria	JW 5/10/13	Yes	No
ICD-O Discrepancy			
Second Synchronous Primary			
Reviewer Initials	M6	Date Reviewed	5-2-13

Source: NCI Genomic Data Commons file 0264d836-79c9-4ae8-85ce-3815e30ebf5f (TCGA-GF-A6C8.45CC145C-9611-4A54-8284-186F233020FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).